Gene-level copy-number profile of tumor specimen TCGA-55-8620-01A from TCGA case TCGA-55-8620, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 60.5 years (22,091 days).
Specimen TCGA-55-8620-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.05e961c5-b6ca-487e-aab8-234c366c150c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-8620-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/edeffeeb-9ac7-46bb-8e29-39b6e88c0881

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 1,539; copy number 2: 32,284; copy number 3: 20,929; copy number 4: 4,186; copy number 5: 378; copy number 6: 248; copy number 7: 92; copy number 8: 15; copy number 17: 17; copy number 18: 26; copy number 22: 36; copy number 24: 6; copy number 41: 32; copy number 55: 22.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-8620-01A-11D-2389-01): tumor purity 0.62, ploidy 2.47, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:59,533,786–59,630,324, 2 genes (within-gene range 0–2): Y_RNA, AC096588.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 872 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:153,396,591–155,614,951, 142 genes, copy number 5 (broad region; genes not listed).
- chr2:142,131,178–143,768,352, 18 genes, copy number 5 (within-gene range 3–5): AC078882.1, UBE2V1P14, RRN3P4, KYNU, SFXN4P1, ARHGAP15, MTCYBP11, MTND6P11, MTND5P24, MTND4P22, MTND4LP12, MTND3P9, MTCO3P5, MTATP6P5, MTCO2P5, AC013437.1, AC079793.1, AC092652.2.
- chr4:54,229,280–55,215,919, 16 genes, copy number 5: PDGFRA, LINC02283, AC098587.1, AC098868.1, LINC02260, KIT, AC097494.1, LINC02358, AC111194.1, RPL38P3, RNU6-410P, AC111194.2, RN7SL424P, KDR, AC021220.2, RN7SL822P.
- chr4:57,424,495–58,118,070, 8 genes, copy number 6: LINC02380, AC013724.1, AC107396.1, AC093725.2, AC093725.1, AC104790.1, SRIP1, AC096725.1.
- chr6:4,341,756–4,347,162, 1 gene, copy number 5: AL159166.1.
- chr7:50,093,279–50,565,405, 11 genes, copy number 5 (within-gene range 1–5): AC034148.1, SPATA48, AC020743.1, AC020743.2, AC020743.3, IKZF1, AC124014.1, RNU6-1091P, FIGNL1, DDC, DDC-AS1.
- chr7:116,563,594–117,230,176, 22 genes, copy number 55 (within-gene range 3–55): COMETT, MET, CAPZA2, AC002543.1, Y_RNA, RNA5SP239, ST7-AS1, AC106873.5, AC106873.7, ST7, ST7-OT4, AC106873.8, AC106873.3, AC106873.2, AC106873.6, AC106873.4, AC106873.1, TPM3P1, MIR6132, ST7-AS2, AC002542.6, AC002542.2.
- chr7:128,207,872–128,775,790, 38 genes, copy number 5: MIR129-1, LEP, AC018635.2, RBM28, AC018635.1, RNU7-27P, PRRT4, IMPDH1, AC010655.1, RNU7-54P, AC010655.4, HILPDA, AC010655.2, AC010655.3, METTL2B, Metazoa_SRP, AC090114.2, AC090114.3, AC090114.1, AC108010.1, AC018638.8, RNU6-177P, AC018638.4, AC018638.2, AC018638.1, AC018638.5, CICP14, AC018638.7, AC018638.3, FAM71F2, AC018638.6, IMP3P2, RNA5SP242, RNA5SP243, FAM71F1, CALU, RN7SL81P, OPN1SW.
- chr7:141,652,381–142,627,399, 78 genes, copy number 7 (broad region; genes not listed).
- chr7:144,397,240–144,836,395, 5 genes, copy number 7 (within-gene range 2–7): NOBOX, PPIAP83, RNU6ATAC40P, TPK1, EEF1A1P10.
- chr7:146,050,062–148,420,998, 4 genes, copy number 6–8 (within-gene range 4–8): AC073308.1, CNTNAP2, AC073418.1, Y_RNA.
- chr7:147,671,711–156,893,216, 207 genes, copy number 5–6 (within-gene range 1–6) (broad region; genes not listed).
- chr11:61,873,519–64,230,686, 129 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr11:71,382,601–71,670,297, 20 genes, copy number 5: ACTE1P, DHCR7, AP002387.1, NADSYN1, MIR6754, AP000867.2, KRTAP5-7, KRTAP5-8, KRTAP5-9, AP000867.5, KRTAP5-10, AP000867.1, KRTAP5-11, KRTAP5-14P, OR7E87P, UNC93B6, OR7E4P, AP000867.3, AP000867.4, RPS3AP41.
- chr11:71,690,453–71,705,404, 2 genes, copy number 5: SNRPCP14, AP003498.1.
- chr13:61,409,685–66,270,458, 36 genes, copy number 22: PCDH20, AL592490.1, LINC02339, RAC1P8, AL353765.1, LINC00358, LINC01075, LINC01074, LINC00459, RPL32P28, AL356102.1, SQSTM1P1, AL445668.1, LINC00448, AL354810.1, LINC00376, AL359208.1, LINC00395, OR7E156P, AL445989.2, AL445989.1, RNU6-81P, PPP1R2P10, AL445238.2, OR7E104P, AL445238.1, LINC00355, NFYAP1, LGMNP1, STARP1, HNRNPA3P5, LINC01052, AL158038.1, MIR548X2, MIR4704, TRIM60P19.
- chr13:71,015,042–73,113,018, 23 genes, copy number 17–24 (within-gene range 1–24): LINC00348, RABEPKP1, DACH1, H3P36, RPL21P109, RPL35AP31, RPS10P21, AL139003.1, RPL18AP17, AL139003.2, AL356754.2, AL356754.1, RPL21P110, RNU6-80P, MZT1, BORA, DIS3, PIBF1, RNU6-79P, PSMD10P3, KLF5, FABP5P1, RNU6-66P.
- chr13:111,865,136–113,974,076, 58 genes, copy number 18–41: LINC00354, AL138691.1, SOX1-OT, SOX1, AL356961.1, LINC00404, LINC01070, LINC01043, LINC01044, SPACA7, TUBGCP3, AL139384.2, ATP11AUN, AL139384.1, ATP11A, ATP11A-AS1, AL356752.1, MCF2L, AL356740.1, MCF2L-AS1, AL356740.2, AL356740.3, F7, F10, F10-AS1, KARS1P2, AL137002.2, PROZ, AL137002.1, PCID2, CUL4A, MIR8075, LDHBP1, LAMP1, GRTP1, AL136221.1, GRTP1-AS1, ADPRHL1, DCUN1D2, DCUN1D2-AS, RNU1-16P, TMCO3, AL442125.2, AL442125.1, TFDP1, ATP4B, GRK1, LINC00552, TMEM255B, GAS6-AS1, GAS6, GAS6-DT, BX072579.1, LINC00454, BX072579.2, LINC00452, LINC00565, C13orf46.
- chr20:34,475,924–35,412,031, 33 genes, copy number 6 (within-gene range 4–6): FDX1P1, AL109923.1, DYNLRB1, Y_RNA, MAP1LC3A, PIGU, AL118520.1, NCOA6, TP53INP2, AL109824.1, HMGB3P1, GGT7, ACSS2, GSS, MYH7B, MIR499A, MIR499B, TRPC4AP, RNU6-407P, EDEM2, AL135844.1, PROCR, AL356652.1, RNA5SP483, MMP24OS, MT1P3, MMP24, AL121753.2, AL121753.1, EIF6, FAM83C-AS1, FAM83C, UQCC1.
- chr20:46,894,624–47,188,844, 1 gene, copy number 7 (within-gene range 4–7): EYA2.
- chr20:47,071,865–47,412,327, 8 genes, copy number 7 (within-gene range 4–7): AL121776.1, AL022342.1, MIR3616, ZMYND8, AL031666.2, AL031666.3, AL031666.1, LINC01754.
- chr20:53,421,199–54,070,594, 12 genes, copy number 8 (within-gene range 4–8): PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1.

Autosomal genes at a single copy (total copy number 1): 1,531. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
